Somatic mutation profile of tumor specimen TCGA-FF-A7CX-01A (aliquot TCGA-FF-A7CX-01A-12D-A382-10) from TCGA case TCGA-FF-A7CX, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 46.3 years (16,924 days).
Specimen TCGA-FF-A7CX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c05d300-33b0-4a3b-82f5-373a88b8672b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FF-A7CX-10A (Blood Derived Normal), aliquot TCGA-FF-A7CX-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c990bd4e-8c94-4bea-95aa-1e455606c23c

The open-access MAF lists 140 somatic variants for this specimen: 96 protein-altering or splice-affecting, 38 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 38, Nonsense Mutation 6, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 3, Intron 2, 3'UTR 2, 5'Flank 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD11 | c.146G>A p.C49Y | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs794729673, CM155254, COSV62718529; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100580104; called by muse, mutect2, varscan2
- ANGPTL8 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs368909299; called by muse, mutect2, varscan2
- APOBEC3D | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV99329112; called by muse, mutect2, varscan2
- ARC | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1262375538, COSV63078041; called by muse, mutect2, varscan2
- ARID2 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 72/173 reads (42%) | catalogued as COSV57603456, COSV57613598; called by muse, mutect2, varscan2
- ASB12 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750364527, COSV62856092; called by muse, mutect2, varscan2
- AWAT2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 84/102 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.046); catalogued as rs769617781, COSV52142773; called by muse, mutect2, varscan2
- BTG1 | c.138G>C p.E46D | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs200623021, COSV55460075; called by muse, mutect2, varscan2
- CABP2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs567869092, COSV99590891; called by muse, mutect2, varscan2
- CCDC180 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as COSV63833447; called by muse, mutect2, varscan2
- CCNC | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 65/81 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV100412664; called by muse, mutect2, varscan2
- CDH22 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.433); catalogued as rs759912387, COSV64838163; called by muse, mutect2, varscan2
- CEP104 | c.2354A>G p.H785R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV100986699; called by muse, mutect2, varscan2
- COL4A1 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 65/69 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101011418; called by muse, mutect2, varscan2
- CPNE2 | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV99321532; called by muse, mutect2, varscan2
- CSNK1A1 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 84/88 reads (95%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV55793508, COSV55798296; called by muse, mutect2, varscan2
- DAB1 | c.1310A>C p.D437A (on ENST00000371231; = p.D404A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV100976506; called by muse, mutect2, varscan2
- DGCR8 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100708108; called by muse, mutect2, varscan2
- DLGAP3 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99333046; called by muse, mutect2, varscan2
- DNAJC10 | c.2265+1G>A p.X755_splice | Splice Site (SNP) | VAF 128/250 reads (51%) | catalogued as COSV99899517; called by muse, mutect2, varscan2
- DNER | c.1453G>A p.V485M | Missense Mutation (SNP) | VAF 104/194 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs760495086, COSV59160311; called by muse, mutect2, varscan2
- DSEL | c.3098C>A p.S1033* | Nonsense Mutation (SNP) | VAF 32/77 reads (42%) | catalogued as COSV100025957, COSV59494476; called by muse, mutect2, varscan2
- EML1 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51755176, COSV99215443; called by muse, mutect2, varscan2
- EPHA2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs780924846, COSV100626138, COSV64452682; called by muse, mutect2, varscan2
- EPHA5 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as rs763166233, COSV99899455; called by muse, mutect2, varscan2
- FNTB | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as rs374785351; called by muse, mutect2, varscan2
- GHSR | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 39/79 reads (49%) | catalogued as rs148371213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPATCH2L | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771836904, COSV99833833; called by muse, mutect2, varscan2
- H3C2 | c.406del p.A136Rfs*? | Frame Shift Del (DEL) | VAF 39/100 reads (39%) | catalogued as COSV52517852; called by mutect2, pindel, varscan2
- HELZ | c.3832C>T p.R1278* | Nonsense Mutation (SNP) | VAF 183/416 reads (44%) | catalogued as COSV100698972; called by muse, mutect2, varscan2
- HOXA9 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs770207656, COSV100604487; called by muse, mutect2, varscan2
- HVCN1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933712812, COSV54372094; called by muse, mutect2, varscan2
- ID3 | c.206T>C p.I69T | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101000786, COSV65801446; called by muse, mutect2, varscan2
- IGKJ5 | c.10T>A p.F4I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | catalogued as rs114105515; called by muse, mutect2, varscan2
- IZUMO2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as rs189762069; called by muse, mutect2, varscan2
- KLF2 | c.76-1G>A p.X26_splice | Splice Site (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99934244; called by muse, varscan2
- KRI1 | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100470340; called by muse, mutect2
- KRT19 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.732); catalogued as rs758090173, COSV99563217; called by muse, mutect2, varscan2
- KRT25 | c.1016C>G p.A339G | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- LRP1B | c.5300T>C p.L1767S | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV101259270; called by muse, mutect2, varscan2
- LRRTM4 | c.1418C>A p.S473Y | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as rs775079691, COSV101297676, COSV69140962; called by muse, mutect2, varscan2
- MAF1 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100075755; called by muse, mutect2, varscan2
- MAP4K3 | c.881A>T p.H294L | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1460355894, COSV99810894; called by muse, mutect2, varscan2
- MBD5 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 49/125 reads (39%) | catalogued as COSV101290222; called by muse, mutect2, varscan2
- MED16 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV99516127; called by muse, mutect2
- MTNR1B | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV99925259; called by muse, mutect2
- MUC15 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1177838995, COSV99846600; called by muse, mutect2
- MYD88 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1353791431, COSV57169680; called by muse, mutect2, varscan2
- MYH8 | c.5783G>A p.R1928Q | Missense Mutation (SNP) | VAF 136/312 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs1316167351, COSV101238610; called by muse, mutect2, varscan2
- MYO5C | c.5024C>T p.P1675L | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99953570; called by muse, mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 26/63 reads (41%) | catalogued as rs772347389; called by mutect2, varscan2
- NDP | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 66/71 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs104894867, CM920503, COSV100955811; called by muse, mutect2, varscan2
- NDUFS1 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs767457281, COSV99261307; called by muse, mutect2, varscan2
- NLRP5 | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.12); catalogued as rs779785587, COSV101173829; called by muse, mutect2, varscan2
- NXPH2 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99741120; called by muse, mutect2, varscan2
- OSBPL6 | c.2318C>A p.S773Y | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99508166; called by muse, mutect2, varscan2
- OTX1 | c.131C>T p.T44I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99246475; called by muse, mutect2, varscan2
- P2RY8 | c.119G>A p.G40D | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1437744214, COSV67177790; called by muse, mutect2, varscan2
- P3H4 | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.16); catalogued as COSV100387956; called by muse, mutect2
- PCDH1 | c.2133C>G p.N711K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746738; called by muse, mutect2, varscan2
- PCSK6 | c.2651G>A p.G884D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100624309; called by muse, mutect2, varscan2
- PDE4A | c.1428T>A p.D476E (on ENST00000380702 / NM_001111307.2; = p.D237E on NM_006202.3) | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV99534901; called by muse, mutect2, varscan2
- PHLDB3 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs767399884, COSV52667496; called by muse, mutect2, varscan2
- PSAPL1 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV100040629; called by muse, mutect2, varscan2
- PSAPL1 | c.530A>T p.Q177L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1376617250, COSV100040632; called by muse, mutect2, varscan2
- RABL2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 103/413 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs760440955, COSV100905694; called by muse, mutect2, varscan2
- RETREG1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100104764; called by muse, mutect2
- RFPL2 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as rs759823818, COSV99964474; called by muse, mutect2, varscan2
- SEC24C | c.1608-1G>A p.X536_splice | Splice Site (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100227083; called by muse, mutect2, varscan2
- SGSM1 | c.545A>C p.Y182S | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241016; called by muse, mutect2, varscan2
- SH3GLB2 | c.15G>A p.M5I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100999371; called by muse, mutect2, varscan2
- SHANK1 | c.4888G>A p.E1630K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as COSV53253144; called by muse, mutect2, varscan2
- SIX6 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59801879, COSV59803007; called by muse, mutect2, varscan2
- SLC19A3 | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99296015; called by muse, mutect2, varscan2
- SLC29A2 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100237185; called by muse, mutect2, varscan2
- SLC6A14 | c.1161T>A p.G387= | Splice Region (SNP) | VAF 84/104 reads (81%) | catalogued as COSV100903205; called by muse, varscan2
- SLCO1B3 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99682015; called by muse, mutect2, varscan2
- SLCO1C1 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.177); catalogued as COSV99859709; called by muse, mutect2, varscan2
- SLCO6A1 | c.278G>A p.C93Y | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV101134796; called by muse, mutect2, varscan2
- SMAD7 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs1302000807, COSV100053011; called by muse, mutect2, varscan2
- SSTR1 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as COSV99943043; called by muse, mutect2, varscan2
- STRN | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as rs1289571315, COSV99815605; called by muse, mutect2, varscan2
- TNFAIP3 | c.295_295+1dup | Frame Shift Ins (INS) | VAF 9/18 reads (50%) | catalogued as COSV52801926; called by mutect2, pindel, varscan2
- TRAPPC8 | c.325G>A p.A109T | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV99351758; called by muse, mutect2, varscan2
- TRIM60 | c.832A>T p.S278C | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100594083; called by muse, mutect2, varscan2
- TUBA3D | c.749T>A p.V250E | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100342793; called by muse, mutect2, varscan2
- TYRO3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.388); catalogued as COSV99777942; called by muse, mutect2, varscan2
- WDPCP | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 61/150 reads (41%) | catalogued as rs894887380, COSV99706359; called by muse, mutect2, varscan2
- ZIC1 | c.238C>A p.H80N | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV51558443, COSV99292239; called by muse, mutect2, varscan2
- ZNF454 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 140/149 reads (94%) | SIFT tolerated (0.47); PolyPhen benign (0.261); catalogued as COSV100195252; called by muse, mutect2, varscan2
- FGD5 | c.1174dup p.A392Gfs*21 | Frame Shift Ins (INS) | VAF 37/85 reads (44%) | called by mutect2, varscan2
- GPR26 | c.81_83del p.L28del | In Frame Del (DEL) | VAF 26/64 reads (41%) | called by pindel, varscan2
- IGKV3-20 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 72/99 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NOTCH2 | c.822_825del p.C275Wfs*120 | Frame Shift Del (DEL) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.1277del p.A426Vfs*17 | Frame Shift Del (DEL) | VAF 90/144 reads (63%) | called by pindel, varscan2
- ABCC11 | c.3609C>T p.G1203= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs773777352, COSV100751023; called by muse, mutect2, varscan2
- ACBD6 | c.132G>A p.E44= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV100852557; called by muse, mutect2
- ANKS1A | c.1242G>A p.P414= | Silent (SNP) | VAF 63/134 reads (47%) | catalogued as rs765405017, COSV100832736, COSV64462746; called by muse, mutect2, varscan2
- ANXA11 | c.48T>A p.A16= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99627422; called by mutect2, varscan2
- BTBD17 | c.1332C>T p.H444= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1257822752; called by muse, mutect2
- COL4A3 | c.1128C>T p.P376= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV101170481; called by muse, mutect2, varscan2
- CPT1B | c.1110C>T p.D370= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV100376787; called by muse, mutect2, varscan2
- DAG1 | c.1206C>T p.R402= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as rs886043253; ClinVar: uncertain significance; called by muse, mutect2
- DCDC1 | c.4836C>A p.G1612= (on ENST00000597505 / NM_001367979.1; = p.G719= on NM_020869.3) | Silent (SNP) | VAF 74/165 reads (45%) | catalogued as COSV100360716; called by muse, mutect2, varscan2
- DCHS1 | c.3756C>T p.I1252= | Silent (SNP) | VAF 11/139 reads (8%) | catalogued as rs1409156864, COSV100202436; called by muse, mutect2
- DOCK7 | c.4818C>A p.G1606= (on ENST00000635253 / NM_001367561.1; = p.G1575= on NM_033407.3) | Silent (SNP) | VAF 101/237 reads (43%) | catalogued as COSV99225512; called by muse, mutect2, varscan2
- EIF2S2 | c.225C>T p.F75= | Silent (SNP) | VAF 144/415 reads (35%) | catalogued as COSV100894992; called by muse, mutect2, varscan2
- FABP6 | c.45G>T p.L15= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV101221274; called by muse, mutect2
- FEZF1 | c.1377G>A p.P459= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1449995015, COSV100484533; called by muse, mutect2, varscan2
- GABBR1 | c.1689C>A p.S563= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100589939; called by muse, mutect2, varscan2
- GNS | c.45C>T p.S15= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs749771186, COSV99253970; called by muse, mutect2, varscan2
- IGHV4-34 | c.88C>T p.L30= | Silent (SNP) | VAF 32/42 reads (76%) | catalogued as rs587760350; called by muse, varscan2
- IRAG1 | c.309C>T p.T103= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as rs373779712; called by muse, mutect2, varscan2
- IRS4 | c.3702C>T p.D1234= | Silent (SNP) | VAF 135/157 reads (86%) | catalogued as COSV64533288; called by mutect2, varscan2
- KCTD8 | c.378G>A p.E126= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100759922; called by muse, mutect2, varscan2
- KIAA1549L | c.4707C>T p.H1569= (on ENST00000321505; = p.H1866= on NM_012194.3) | Silent (SNP) | VAF 60/119 reads (50%) | catalogued as rs760804877, COSV104395370, COSV58587375; called by muse, mutect2, varscan2
- KMT2C | c.4248G>A p.S1416= | Silent (SNP) | VAF 78/191 reads (41%) | catalogued as rs200269228, COSV51476129; called by muse, mutect2, varscan2
- KRT17 | c.1272C>T p.R424= | Silent (SNP) | VAF 148/328 reads (45%) | catalogued as rs575174355, COSV60860413; called by muse, mutect2, varscan2
- MUC5B | c.14859G>A p.S4953= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs200564889, COSV101500633; called by muse, mutect2, varscan2
- PLXDC2 | c.600A>T p.A200= | Silent (SNP) | VAF 78/198 reads (39%) | catalogued as COSV101023196; called by muse, mutect2, varscan2
- PRDM9 | c.1515T>C p.N505= | Silent (SNP) | VAF 43/83 reads (52%) | catalogued as COSV57005758; called by muse, mutect2, varscan2
- PRSS16 | c.861G>A p.A287= | Silent (SNP) | VAF 56/127 reads (44%) | catalogued as rs773708165, COSV100041910; called by muse, mutect2, varscan2
- PTPRF | c.5205C>T p.I1735= | Silent (SNP) | VAF 74/163 reads (45%) | catalogued as COSV100741112; called by muse, mutect2, varscan2
- PXDN | c.786C>T p.T262= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as rs765748537, COSV53237975; called by muse, mutect2, varscan2
- RGS3 | c.2628G>T p.S876= (on ENST00000350696 / NM_001282923.2; = p.S595= on NM_130795.4) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100636915; called by muse, mutect2, varscan2
- RITA1 | c.273C>T p.T91= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1382511932, COSV100014101, COSV100014117; called by muse, mutect2, varscan2
- SUPT5H | c.606C>A p.A202= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV100782130; called by muse, mutect2, varscan2
- SYNDIG1 | c.606C>T p.Y202= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs753567279, COSV100965392; called by muse, mutect2, varscan2
- TFAP2B | c.255C>A p.P85= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV53827799, COSV53830242; called by muse, mutect2, varscan2
- TFR2 | c.1287C>T p.I429= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs747965768, COSV99774680; called by muse, mutect2, varscan2
- THAP6 | c.480C>T p.G160= | Silent (SNP) | VAF 90/209 reads (43%) | catalogued as rs767607083, COSV61162406; called by muse, mutect2, varscan2
- THOC1 | c.1539G>A p.Q513= | Silent (SNP) | VAF 72/93 reads (77%) | catalogued as COSV99863554; called by muse, mutect2, varscan2
- ZAN | c.3150C>T p.Y1050= | Silent (SNP) | VAF 43/71 reads (61%) | catalogued as rs1262302919, COSV61806797; called by muse, mutect2, varscan2
- EPHA8 | c.1315+18G>A | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs199679973, COSV51273871; called by muse, mutect2, varscan2
- FRMPD2B | n.903C>A | RNA (SNP) | VAF 82/393 reads (21%) | called by muse, mutect2, varscan2
- KRTCAP2 | chr1:155173281 G>A | 5'Flank (SNP) | VAF 77/85 reads (91%) | catalogued as rs551900242, COSV55280358; called by muse, mutect2, varscan2
- SLC48A1 | c.*606G>A | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs374167422; called by muse, varscan2
- SLC9A8 | c.*1C>T | 3'UTR (SNP) | VAF 27/56 reads (48%) | catalogued as rs367961630; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23329G>A | Intron (SNP) | VAF 39/94 reads (41%) | catalogued as rs756391897, COSV59392090; called by muse, mutect2, varscan2
